Gene-level copy-number profile of specimen HCM-SANG-0528-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0528-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0528-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be98266f-a4d4-4409-bfe7-4ccac511682b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0528-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/467c30ac-3134-4533-8ede-147c16d7a414

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 536; copy number 2: 14,762; copy number 3: 26,482; copy number 4: 12,856; copy number 5: 2,619; copy number 6: 953; copy number 7: 134; copy number 8: 4.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:119,159,297–119,349,761, 4 genes (within-gene range 0–2): AL022722.2, MAN1A1, AL022722.1, RNU6-194P.
- chr7:45,769,105–45,843,740, 6 genes: GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr17:11,998,353–12,790,242, 11 genes (within-gene range 0–2): AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1.
- chr18:50,879,080–51,688,209, 13 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 138 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–5,691,488, 75 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:5,810,641–9,712,920, 58 genes, copy number 7–8: LINC01810, SILC1, MIR7158, AC017053.1, LINC01247, LINC01824, PIK3CDP1, MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2, RSAD2, AC017076.1, GRASLND, RNF144A, AC068481.1, RN7SKP112, AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2, LINC00299, U91324.1, LINC01814, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4.
- chr2:85,315,041–85,332,996, 3 genes, copy number 7: AC093162.1, TGOLN2, Y_RNA.
- chr2:87,125,198–87,196,629, 2 genes, copy number 7: AC083899.1, MIR4771-1.

Autosomal genes at a single copy (total copy number 1): 536. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
